Somatic mutation profile of tumor specimen TCGA-ZF-A9RD-01A (aliquot TCGA-ZF-A9RD-01A-11D-A42E-08) from TCGA case TCGA-ZF-A9RD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.3 years (27,496 days).
Specimen TCGA-ZF-A9RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4081db99-915b-49fa-8e9d-ba582fb6fb19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9RD-10A (Blood Derived Normal), aliquot TCGA-ZF-A9RD-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e82524e-f5d2-4781-8833-d5792e6746b4

The open-access MAF lists 195 somatic variants for this specimen: 136 protein-altering or splice-affecting, 54 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 54, Nonsense Mutation 12, Intron 3, Splice Site 3, Splice Region 1, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.1479G>C p.K493N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV64984378, COSV64986200; called by muse, mutect2, varscan2
- ACCSL | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV66579846; called by muse, mutect2, varscan2
- ADAM17 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.115); catalogued as COSV60397345; called by muse, mutect2, varscan2
- ADCY6 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166034; called by muse, mutect2, varscan2
- ADCY6 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs763633558, COSV57166039; called by muse, mutect2, varscan2
- ALMS1 | c.4367C>T p.S1456L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1395655276, COSV52501553; called by muse, mutect2, varscan2
- ANKRD52 | c.2700G>C p.E900D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV57281869; called by muse, mutect2, varscan2
- ANKS4B | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61138627; called by muse, mutect2, varscan2
- AP3B2 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760853121, COSV55606048; called by muse, mutect2, varscan2
- APOB | c.6444G>T p.K2148N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51921617; called by muse, mutect2
- ARSB | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53718492; called by muse, mutect2, varscan2
- ASIC2 | c.1196+1G>C p.X399_splice | Splice Site (SNP) | VAF 29/76 reads (38%) | catalogued as COSV56754829; called by muse, mutect2, varscan2
- BRD8 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs776463836, COSV50145023; called by muse, mutect2, varscan2
- C3orf20 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV53782132; called by muse, mutect2, varscan2
- CACNG7 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV55812805; called by muse, mutect2, varscan2
- CBLC | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV54321174; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 60/132 reads (45%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- CDR1 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 43/146 reads (29%) | catalogued as rs1333140902, COSV65164410; called by muse, mutect2, varscan2
- CKMT2 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV54172026; called by muse, mutect2, varscan2
- CNOT1 | c.5501C>G p.S1834C | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV55312421; called by muse, mutect2, varscan2
- COL27A1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs745631704, COSV61921043, COSV61926792; called by muse, mutect2, varscan2
- CYP1A2 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59658958; called by muse, mutect2, varscan2
- DAB2IP | c.967G>T p.G323C (on ENST00000408936; = p.G295C on NM_032552.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1161361470, COSV99405447; called by muse, mutect2, varscan2
- DCAF8L1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.254); catalogued as COSV71595088; called by muse, mutect2, varscan2
- DDX24 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763198073, COSV58211662; called by muse, mutect2, varscan2
- DDX3X | c.1085G>A p.R362K (on ENST00000399959; = p.R363K on NM_001356.5) | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV67863004; called by muse, mutect2, varscan2
- DNAH17 | c.11428G>A p.E3810K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs774747332, COSV67749211; called by muse, mutect2, varscan2
- DNAH3 | c.9229C>T p.R3077C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372316224; called by muse, mutect2, varscan2
- DOP1B | c.6661G>C p.D2221H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV67690552, COSV67690819; called by muse, mutect2, varscan2
- DUSP11 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV55593548; called by muse, varscan2
- EFNA2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV99288983; called by muse, mutect2
- EPB41L3 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV59442986, COSV59453034; called by muse, mutect2
- FBN1 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.27); catalogued as COSV57308212; called by muse, mutect2, varscan2
- FCRL4 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV54859316; called by muse, mutect2, varscan2
- FHL2 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59078678, COSV59078884; called by muse, mutect2, varscan2
- GANAB | c.1812C>G p.F604L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV100647820, COSV60461444; called by muse, varscan2
- GLS | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100290081, COSV57843459; called by muse, mutect2
- GOLGA4 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62708959; called by muse, mutect2, varscan2
- GPR149 | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780077517, COSV67665536; called by muse, mutect2, varscan2
- GPRC5C | c.700C>T p.Q234* (on ENST00000652232; = p.Q189* on NM_018653.4) | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV100702886; called by muse, mutect2, varscan2
- GRTP1 | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV58148167; called by muse, mutect2, varscan2
- HCRTR2 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100904357; called by muse, mutect2
- HDAC1 | c.611A>C p.Y204S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV65190315; called by muse, mutect2, varscan2
- HSPB11 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV52040163, COSV52042075; called by muse, mutect2, varscan2
- IGHG1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs587714136; called by muse, mutect2, varscan2
- ITGAV | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV53708780; called by muse, mutect2, varscan2
- KDM5B | c.4372G>T p.E1458* | Nonsense Mutation (SNP) | VAF 76/271 reads (28%) | catalogued as COSV99350601; called by muse, mutect2, varscan2
- KDM6A | c.3549-1G>C p.X1183_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as CS1412301, COSV65036810, COSV65040147; called by muse, mutect2, varscan2
- KIF18A | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV54180632; called by muse, mutect2, varscan2
- KIF21A | c.2206C>T p.Q736* (on ENST00000361418 / NM_001378440.1; = p.Q723* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/75 reads (5%) | catalogued as COSV100735464; called by muse, mutect2
- KLHL6 | c.1280G>C p.G427A | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384224, COSV58064261; called by muse, mutect2, varscan2
- LATS2 | c.1977G>C p.K659N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66873210; called by muse, mutect2, varscan2
- LCE2A | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as COSV64226656, COSV64227115; called by muse, mutect2, varscan2
- LLGL2 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51341647; called by muse, mutect2, varscan2
- LRPPRC | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53233428; called by muse, mutect2, varscan2
- LRRC36 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as rs776178910, COSV52081077; called by muse, mutect2, varscan2
- LRRTM1 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54437796; called by muse, mutect2, varscan2
- MAP2K5 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461652088, COSV51609436, COSV99460171; called by muse, mutect2, varscan2
- MICAL2 | c.5351G>A p.R1784K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs1422276993, COSV56283990; called by muse, mutect2, varscan2
- MOGAT1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs775805988, COSV71479789; called by muse, mutect2, varscan2
- MUC16 | c.42582G>C p.Q14194H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV66689460, COSV66691422; called by muse, mutect2, varscan2
- MVD | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV55367725; called by muse, mutect2, varscan2
- MYO16 | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV51775985; called by muse, mutect2
- NEMF | c.2243C>G p.S748C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV53589031; called by muse, mutect2, varscan2
- NOL8 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1482134395, COSV62633930; called by muse, mutect2, varscan2
- NR5A2 | c.814G>C p.E272Q (on ENST00000367362 / NM_205860.3; = p.E226Q on NM_003822.5) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as COSV52644237; called by muse, mutect2, varscan2
- OGN | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs943485645, COSV52760226, COSV52760887; called by muse, mutect2, varscan2
- OR8I2 | c.532dup p.C178Lfs*2 | Frame Shift Ins (INS) | VAF 22/144 reads (15%) | catalogued as rs112181516; called by mutect2, varscan2
- PAPOLG | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772397961, COSV53180972; called by muse, mutect2, varscan2
- PCDHB14 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1554289183, COSV53386234; called by muse, mutect2, varscan2
- PCDHGA5 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV53893076; called by muse, mutect2, varscan2
- PGK1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV64831569; called by muse, mutect2, varscan2
- PLK4 | c.1794G>T p.R598S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54636080; called by muse, mutect2, varscan2
- PLS3 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CD147865, COSV56776064; called by muse, mutect2, varscan2
- PNISR | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.059); catalogued as COSV65078467; called by muse, mutect2, varscan2
- PON1 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV55930473; called by muse, mutect2, varscan2
- PPP1R3C | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs201093907; called by muse, mutect2, varscan2
- PRAME | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as rs935148315, COSV101287087; called by muse, mutect2, varscan2
- PRTN3 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99311532; called by muse, mutect2, varscan2
- PTCH1 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs146616780, COSV59467250; called by muse, mutect2, varscan2
- PTCH1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); catalogued as COSV59461287; called by muse, mutect2, varscan2
- PTPN11 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV61004806; called by muse, mutect2, varscan2
- RBBP6 | c.4613G>C p.R1538T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV60502843; called by muse, mutect2, varscan2
- RETREG1 | c.1175C>G p.S392* (on ENST00000306320 / NM_001034850.2; = p.S251* on NM_019000.4) | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100104348; called by muse, mutect2, varscan2
- RPA3 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56187219, COSV56187412; called by muse, mutect2, varscan2
- RPRM | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57988449; called by muse, mutect2, varscan2
- RYR2 | c.12190G>A p.E4064K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV63665627; called by muse, mutect2, varscan2
- SCARF1 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99557046; called by muse, mutect2, varscan2
- SCARF1 | c.1942C>G p.P648A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV53957134; called by muse, mutect2, varscan2
- SETD2 | c.4083G>C p.Q1361H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV57428860; called by muse, mutect2, varscan2
- SH3PXD2B | c.1013-1G>T p.X338_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV61124404; called by muse, mutect2, varscan2
- SLC26A4 | c.554G>T p.R185I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM121742, COSV55914198; called by muse, mutect2, varscan2
- SLC38A8 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV55304104; called by muse, mutect2, varscan2
- SLC39A10 | c.829C>G p.H277D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs1217627521, COSV62766079; called by muse, mutect2, varscan2
- SLC4A7 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.628); catalogued as COSV55395462; called by muse, varscan2
- SMCO1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV58836573; called by muse, mutect2, varscan2
- SNRNP200 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs370235055; called by muse, mutect2
- SPATA2 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.346); catalogued as rs1032829726, COSV56865258; called by muse, mutect2, varscan2
- SPATA31E1 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.155); catalogued as COSV57789327; called by muse, mutect2, varscan2
- SPG11 | c.5659G>C p.D1887H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55990325; called by muse, mutect2, varscan2
- ST20 | c.140A>C p.E47A | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV99358189; called by muse, mutect2
- STAG2 | c.3417G>A p.M1139I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54349927; called by muse, mutect2, varscan2
- SUN3 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs914247591, COSV52048336; called by muse, mutect2, varscan2
- SVBP | c.117C>A p.I39= | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as COSV65304849; called by muse, mutect2, varscan2
- SVOPL | c.554C>T p.S185F (on ENST00000419765; = p.S33F on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55988235; called by muse, mutect2, varscan2
- SYT10 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 30/173 reads (17%) | catalogued as COSV57341346, COSV99951367; called by muse, mutect2, varscan2
- TAB3 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs1247802956, COSV55834004, COSV55836369; called by muse, mutect2, varscan2
- TAF6 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100612711; called by muse, mutect2, varscan2
- TAOK3 | c.1312A>G p.I438V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV66824587; called by muse, mutect2, varscan2
- TFE3 | c.1072A>T p.R358W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59945807; called by muse, mutect2, varscan2
- TIPIN | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV56019138; called by muse, mutect2, varscan2
- TRAPPC10 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1348310545, COSV52375248; called by muse, mutect2, varscan2
- TRMT2A | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); catalogued as rs1209800510, COSV99349998; called by muse, mutect2, varscan2
- TRPM3 | c.436T>A p.F146I (on ENST00000357533 / NM_001366142.2; = p.F115I on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV62467075; called by muse, mutect2, varscan2
- TTC7B | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.815); catalogued as rs1355435067, COSV60624275; called by muse, mutect2, varscan2
- TUT4 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.942); catalogued as COSV57109400; called by muse, mutect2, varscan2
- USP45 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV59678149; called by muse, mutect2, varscan2
- VDAC1 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs1403417870, COSV54736554; called by muse, mutect2, varscan2
- VPS13D | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); catalogued as COSV62524575, COSV62534073; called by muse, mutect2
- VWC2L | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464105210, COSV56964842; called by muse, mutect2, varscan2
- YLPM1 | c.5807A>C p.D1936A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99459676; called by muse, mutect2, varscan2
- ZFHX4 | c.10818C>G p.F3606L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.18); catalogued as COSV51482507, COSV99262671; called by muse, mutect2, varscan2
- ZFYVE28 | c.840C>A p.H280Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.772); catalogued as COSV52106430; called by muse, mutect2, varscan2
- ZGRF1 | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1230744696, COSV101500612; called by muse, mutect2, varscan2
- ZNF182 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59355754; called by muse, mutect2, varscan2
- ZNF217 | c.1538C>G p.S513C | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56593435; called by muse, mutect2, varscan2
- ZNF225 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV53470758; called by muse, mutect2, varscan2
- ZNF350 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54707438; called by muse, mutect2
- ZNF410 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV57909355; called by muse, mutect2, varscan2
- ZNF436 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); catalogued as COSV58357928, COSV58359374; called by muse, mutect2, varscan2
- ZNF462 | c.4021G>C p.D1341H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52929204; called by muse, mutect2, varscan2
- ZNF581 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV54401141; called by muse, mutect2, varscan2
- ZNF583 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52400776; called by muse, mutect2, varscan2
- ZNF839 | c.1786C>T p.P596S (on ENST00000558850 / NM_001267827.1; = p.P712S on NM_018335.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV51755868; called by muse, mutect2, varscan2
- ZZEF1 | c.5933C>T p.P1978L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs755762266, COSV67555775; called by muse, mutect2, varscan2
- ADCY6 | c.216G>A p.R72= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV57166045; called by muse, mutect2, varscan2
- ANGPT2 | c.384G>A p.G128= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV57334654; called by muse, mutect2, varscan2
- C3 | c.2541C>T p.I847= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55567987; called by muse, mutect2, varscan2
- CAMK2G | c.396C>T p.I132= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1291090817, COSV59479790; called by muse, mutect2, varscan2
- CATSPER3 | c.984G>A p.K328= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV50945179; called by muse, mutect2, varscan2
- CCNJL | c.1101G>A p.G367= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs759656265, COSV57442894; called by muse, mutect2
- CD163L1 | c.1890C>T p.I630= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs267603676, COSV58010436; called by muse, mutect2, varscan2
- CENPO | c.612C>T p.L204= | Silent (SNP) | VAF 86/501 reads (17%) | catalogued as COSV53163910, COSV53173391; called by muse, mutect2, varscan2
- CHD6 | c.2163C>T p.F721= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as COSV58553390; called by muse, mutect2, varscan2
- CHML | c.1158C>T p.P386= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV59362230; called by muse, mutect2, varscan2
- CLCN5 | c.2202G>A p.Q734= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV56582100; called by muse, mutect2, varscan2
- COBL | c.174G>T p.L58= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54336958, COSV54342947; called by muse, mutect2
- CYP1A2 | c.516G>C p.L172= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs1237180124, COSV59658967; called by muse, mutect2, varscan2
- CYTH3 | c.163C>T p.L55= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV63437230; called by muse, mutect2, varscan2
- DCHS1 | c.285C>T p.D95= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs773367423, COSV55029733, COSV55033147; called by muse, mutect2, varscan2
- DCUN1D3 | c.525A>G p.Q175= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as COSV60952242; called by muse, mutect2
- DNAH17 | c.7416G>C p.L2472= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV67749212; called by muse, mutect2
- EPHA3 | c.1326G>A p.T442= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs552354794, COSV60692591; called by muse, mutect2, varscan2
- FAM83G | c.936C>A p.L312= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100525505, COSV58755028; called by muse, mutect2, varscan2
- FBXO34 | c.1047T>C p.D349= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58253102; called by muse, mutect2, varscan2
- GALNTL6 | c.45C>T p.F15= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV72552862, COSV72552990; called by muse, mutect2, varscan2
- GRID1 | c.624C>T p.L208= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as COSV60012078; called by muse, mutect2, varscan2
- KCNF1 | c.1440G>A p.L480= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV54461890; called by muse, mutect2, varscan2
- KIF27 | c.3663G>A p.K1221= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs1443363454, COSV52824803; called by muse, mutect2, varscan2
- KIR3DL2 | c.459C>T p.F153= | Silent (SNP) | VAF 37/277 reads (13%) | called by muse, mutect2, varscan2
- KPNA6 | c.114C>G p.L38= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV65359132; called by muse, mutect2, varscan2
- LDB2 | c.955C>T p.L319= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV58761796; called by muse, mutect2, varscan2
- MMP24 | c.390G>A p.T130= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs757018501, COSV55768211; called by muse, mutect2, varscan2
- MTARC2 | c.405G>A p.L135= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV63764930; called by muse, mutect2, varscan2
- NUP85 | c.613C>T p.L205= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs1490476071, COSV55462624; called by muse, mutect2, varscan2
- NVL | c.1659G>C p.L553= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV55869685; called by muse, mutect2, varscan2
- PARK7 | c.132A>G p.V44= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1014727907, COSV58579420; called by muse, mutect2, varscan2
- PCDH8 | c.2262C>T p.I754= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1466304483, COSV58810607; called by muse, mutect2
- PCDHA1 | c.1329G>A p.V443= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV65372434; called by muse, mutect2, varscan2
- PIWIL4 | c.2310G>A p.L770= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV54406892; called by muse, mutect2, varscan2
- RARS1 | c.306G>A p.V102= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV51561712; called by muse, mutect2, varscan2
- RBFOX1 | c.1044A>C p.P348= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV60943547; called by muse, mutect2
- RNASEL | c.1740G>A p.L580= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV62376136; called by muse, mutect2, varscan2
- RNPEPL1 | c.1038C>T p.F346= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs765045975, COSV54371743; called by muse, mutect2, varscan2
- RPH3A | c.1131G>A p.E377= (on ENST00000389385 / NM_001143854.2; = p.E373= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs751718164, COSV66989865; called by muse, mutect2, varscan2
- RPRML | c.270C>T p.N90= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100461960; called by muse, mutect2
- RPS6KA4 | c.726C>T p.G242= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs370934199; called by muse, varscan2
- RTTN | c.6522G>A p.Q2174= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV55340838; called by muse, mutect2, varscan2
- SBDS | c.669A>G p.L223= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV55887012; called by muse, mutect2, varscan2
- SBSN | c.270C>G p.L90= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV71732993; called by muse, mutect2, varscan2
- SEC24A | c.2223G>A p.R741= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV59745607; called by muse, mutect2, varscan2
- SERPINA10 | c.357G>A p.P119= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs1281319741, COSV56227356; called by muse, mutect2, varscan2
- SMCR8 | c.282C>T p.I94= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as rs757358379, COSV58174615; called by muse, mutect2, varscan2
- SNRPD2 | c.300C>T p.F100= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV50003455; called by muse, mutect2, varscan2
- SNRPD2 | c.96C>G p.L32= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV50003457; called by muse, mutect2, varscan2
- THAP4 | c.1023C>T p.L341= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs932383791, COSV67190515, COSV67192868; called by muse, mutect2, varscan2
- TTN | c.13491C>T p.F4497= (on ENST00000591111; = p.F3570= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV59865410, COSV60070882; called by muse, mutect2, varscan2
- WDR26 | c.741C>T p.L247= (on ENST00000414423 / NM_001379403.1; = p.L147= on NM_025160.7) | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV54352795; called by muse, mutect2, varscan2
- ZNF831 | c.1020G>A p.E340= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV64036945; called by muse, mutect2
- COX6B1 | c.-12+9C>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs1160709204, COSV55836909; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14635T>A | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100230721; called by muse, mutect2, varscan2
- FKBP7 | c.-1G>A | 5'UTR (SNP) | VAF 30/192 reads (16%) | catalogued as COSV99247588; called by muse, mutect2, varscan2
- OBSCN | c.11660-2603C>T | Intron (SNP) | VAF 29/112 reads (26%) | catalogued as rs753584750, COSV52735756; called by muse, mutect2, varscan2
- STMP1 | chr7:135660503 C>G | 5'Flank (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
